Surgical pathology report (de-identified scan), TCGA case TCGA-CI-6621, project TCGA-READ (Rectum Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-CI-6621-01A (Primary Tumor).

Pre-Op Diagnosis: Abdominal pain

Post-Op Diagnosis: Polyp/mass

CGA - CI - 6621

Final Pathologic Diagnosis:

Collection Date: [REDACTED]

PART A:

PROXIMAL ASCENDING (COLON, POLYP):

FRAGMENTS OF TUBULOVILLOUS ADENOMATOUS POLYP OF COLON
NEGATIVE FOR HIGH GRADE DYSPLASIA.

PART B:

RECTUM (MASS, BIOPSIES):

INVASIVE ADENOCARCINOMA, MODERATELY DIFFERENTIATED, WITH
FOCAL ULCERATION AND NECROSIS OF RECTUM.

Source: NCI Genomic Data Commons file e6bac7e2-f101-4082-bcc5-51e6fcee606a (TCGA-CI-6621.75FBB034-4262-4263-A5D8-57D22B55A915.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).